Somatic mutation profile of tumor specimen TCGA-VQ-A8PM-01A (aliquot TCGA-VQ-A8PM-01A-21D-A410-08) from TCGA case TCGA-VQ-A8PM, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Signet ring cell carcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.6 years (20,665 days).
Specimen TCGA-VQ-A8PM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8894c212-d9f2-4d02-9759-54a8d5a1fcb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8PM-10A (Blood Derived Normal), aliquot TCGA-VQ-A8PM-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c48d8892-0a13-40ae-a655-b970386723e7

The open-access MAF lists 53 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 35, Silent 14, Nonsense Mutation 2, Frame Shift Del 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FANCE | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs763151358, COSV57690092; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- AGPS | c.386A>C p.K129T | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV99931634; called by muse, mutect2, varscan2
- ANO8 | c.1318A>G p.K440E | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99344828; called by muse, mutect2, varscan2
- ARHGEF11 | c.1454T>A p.I485N | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100810394; called by muse, mutect2, varscan2
- ARHGEF11 | c.1453A>T p.I485F | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100810395; called by muse, mutect2, varscan2
- ATG7 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV100607790, COSV61615989; called by muse, mutect2, varscan2
- ATP5F1A | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56361707, COSV99959117; called by muse, mutect2, varscan2
- BRD1 | c.2261A>G p.K754R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV99350156; called by muse, mutect2, varscan2
- CSMD3 | c.3881T>C p.L1294P (on ENST00000297405 / NM_001363185.1; = p.L1190P on NM_052900.3) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99835960, COSV99844015, COSV99852330; called by muse, mutect2
- DCLRE1A | c.1903A>C p.K635Q | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV100800461; called by muse, mutect2, varscan2
- DNAJC13 | c.6478del p.V2160Lfs*7 | Frame Shift Del (DEL) | VAF 12/77 reads (16%) | catalogued as COSV53458804, COSV99038227; called by mutect2, pindel, varscan2
- FAM114A2 | c.976C>T p.P326S | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs1198291448, COSV100697776; called by muse, mutect2
- IFT52 | c.392T>A p.V131D | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV100887663; called by muse, mutect2
- KRTAP10-9 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs587748715, COSV59973088; called by muse, mutect2
- LETMD1 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100016495, COSV50400093; called by muse, mutect2, varscan2
- LGR4 | c.659G>A p.C220Y | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101004353; called by muse, mutect2, varscan2
- LRRTM3 | c.1085G>A p.G362D | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs146764802; called by muse, mutect2, varscan2
- MAPK9 | c.466A>G p.N156D | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100558554; called by muse, mutect2, varscan2
- MTMR2 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 10/103 reads (10%) | catalogued as COSV60578484, COSV60581426; called by muse, mutect2
- MYOM3 | c.1456A>G p.K486E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.035); catalogued as COSV100293599; called by muse, mutect2
- NAT9 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.232); catalogued as COSV52852767; called by muse, mutect2, varscan2
- NAV3 | c.3046A>C p.T1016P | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV99894344; called by muse, mutect2
- NAV3 | c.4483A>G p.S1495G | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV99894345; called by muse, mutect2, varscan2
- NDUFAF1 | c.244T>G p.F82V | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99531540; called by muse, mutect2, varscan2
- NR2F2 | c.1076G>A p.R359K | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV101241150, COSV67683391; called by muse, mutect2, varscan2
- OR13F1 | c.101T>G p.M34R | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV100594829; called by muse, mutect2, varscan2
- OR2AK2 | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.959); catalogued as COSV100824268; called by muse, mutect2, varscan2
- OTOP2 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs201521524, COSV58881528; called by muse, mutect2, varscan2
- PCDH9 | c.3714A>C p.*1238Yext*26 (on ENST00000377865 / NM_203487.3; = p.*1204Yext*26 on NM_020403.5 and 1 other RefSeq transcript) | Nonstop Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV60531117, COSV60535317, COSV60559707; called by muse, mutect2, varscan2
- PGBD1 | c.1249T>G p.L417V | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99460768; called by muse, mutect2, varscan2
- RAB3D | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 38/237 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.897); catalogued as rs112584280; called by muse, mutect2, varscan2
- SAFB2 | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs201263017, COSV99385975; called by muse, mutect2, varscan2
- SHROOM4 | c.1760G>A p.R587H | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557255126, COSV56791158, COSV99174248; called by muse, mutect2, varscan2
- SLFN13 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.287); catalogued as COSV99540267; called by muse, mutect2
- SYNPO2L | c.1156C>T p.R386* (on ENST00000394810 / NM_001114133.3; = p.R162* on NM_024875.5) | Nonsense Mutation (SNP) | VAF 14/80 reads (18%) | catalogued as rs763416831, COSV100866434; called by muse, mutect2, varscan2
- TUBA3C | c.799T>G p.F267V | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1488755151, COSV101262821; called by muse, mutect2, varscan2
- USP47 | c.376C>T p.H126Y (on ENST00000399455 / NM_001372095.1; = p.H38Y on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/109 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.099); catalogued as COSV60460531; called by muse, mutect2
- ZKSCAN3 | c.1046A>G p.K349R | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99357092; called by muse, mutect2, varscan2
- ZNF521 | c.3437A>C p.K1146T | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100833107; called by muse, mutect2, varscan2
- AJAP1 | c.180G>A p.P60= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as rs1372339462, COSV100981473; called by muse, mutect2, varscan2
- CHDH | c.579G>A p.K193= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs761318873, COSV100179826; called by muse, varscan2
- EHD4 | c.1221G>A p.T407= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs749063815, COSV55005223; called by muse, mutect2, varscan2
- ELOA2 | c.1674T>C p.V558= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV99797637; called by muse, mutect2, varscan2
- EYA4 | c.333G>T p.T111= | Silent (SNP) | VAF 21/172 reads (12%) | catalogued as rs780325672, COSV62058045; called by muse, mutect2, varscan2
- KCNMB1 | c.525C>T p.I175= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as rs763259592, COSV51134326; called by muse, mutect2, varscan2
- KLHL15 | c.837A>G p.K279= | Silent (SNP) | VAF 6/103 reads (6%) | catalogued as COSV100044382; called by muse, mutect2
- MYH2 | c.1281A>T p.V427= | Silent (SNP) | VAF 32/170 reads (19%) | catalogued as COSV99820731; called by muse, mutect2, varscan2
- NELL1 | c.714A>G p.Q238= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100123901; called by muse, mutect2
- NSD2 | c.1746G>A p.K582= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100373742; called by muse, mutect2, varscan2
- PDZRN3 | c.2568C>A p.G856= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs752713637, COSV55207524; called by muse, mutect2, varscan2
- PRR30 | c.63T>G p.T21= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV99574741; called by muse, mutect2, varscan2
- SCAF8 | c.2547A>T p.L849= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as COSV100914249; called by muse, mutect2, varscan2
- ZNF470 | c.1272T>C p.P424= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100401353; called by muse, mutect2, varscan2
